Somatic mutation profile of tumor specimen TCGA-FB-AAPS-01A (aliquot TCGA-FB-AAPS-01A-12D-A397-08) from TCGA case TCGA-FB-AAPS, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 62.9 years (22,981 days).
Specimen TCGA-FB-AAPS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60d05648-e71a-45e7-8039-6d4c57ab3ee2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FB-AAPS-11A (Solid Tissue Normal), aliquot TCGA-FB-AAPS-11A-11D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc390830-ee4c-46be-a911-e77c772d3740

The open-access MAF lists 27 somatic variants for this specimen: 25 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 23, Silent 2, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 27/385 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ACSL4 | c.722G>A p.G241E (on ENST00000340800 / NM_022977.2; = p.G200E on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/525 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as COSV100538659; called by muse, mutect2, varscan2
- ATG2B | c.3654C>A p.F1218L | Missense Mutation (SNP) | VAF 18/342 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55891458; called by muse, mutect2
- CATSPERG | c.2899G>A p.E967K | Missense Mutation (SNP) | VAF 81/1405 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.633); catalogued as rs147603617; called by muse, mutect2
- CDH23 | c.3503G>A p.R1168Q | Missense Mutation (SNP) | VAF 27/266 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as rs727502925, COSV56473232; ClinVar: uncertain significance; called by muse, mutect2
- CXorf21 | c.832T>A p.L278M | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV100973368; called by muse, mutect2
- DGCR2 | c.605G>T p.R202L | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.162); catalogued as rs1403885691, COSV99594062; called by muse, mutect2
- FLT1 | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 22/427 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs764045713, COSV56718083; called by muse, mutect2
- FTMT | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs368526431; called by muse, mutect2
- KIR3DL1 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 46/714 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs779002817, COSV58491658; called by muse, mutect2
- KMT2B | c.3869G>A p.R1290H | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs866662490; called by muse, mutect2
- LGR4 | c.2021C>T p.T674I | Missense Mutation (SNP) | VAF 20/410 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.037); catalogued as rs1230225322, COSV100156714; called by muse, mutect2
- MTUS2 | c.233T>A p.F78Y | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.176); catalogued as COSV101462382; called by muse, mutect2
- MYO16 | c.5467G>A p.E1823K | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.681); catalogued as COSV100696951, COSV100697470; called by muse, mutect2, varscan2
- NXNL1 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 25/378 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.162); catalogued as rs371790764; called by muse, mutect2
- PRAG1 | c.3362G>A p.R1121H | Missense Mutation (SNP) | VAF 42/860 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as COSV58160294; called by muse, mutect2
- RNF220 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 24/530 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs1291731673, COSV100698566; called by muse, mutect2
- RREB1 | c.936G>T p.E312D | Missense Mutation (SNP) | VAF 11/230 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.043); catalogued as COSV100619897; called by muse, mutect2
- RREB1 | c.937C>T p.Q313* | Nonsense Mutation (SNP) | VAF 12/232 reads (5%) | catalogued as COSV100619900; called by muse, mutect2
- RSPO1 | c.438G>A p.A146= | Splice Region (SNP) | VAF 40/356 reads (11%) | catalogued as rs202233461; called by muse, mutect2, varscan2
- SYNPO2 | c.3358G>A p.D1120N | Missense Mutation (SNP) | VAF 22/416 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs1308307269, COSV61110699; called by muse, mutect2
- TMEM215 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 14/300 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as rs1314691964, COSV100713265; called by muse, mutect2
- TTN | c.62404C>T p.R20802C (on ENST00000591111; = p.R13378C on NM_003319.4) | Missense Mutation (SNP) | VAF 29/395 reads (7%) | PolyPhen possibly damaging (0.731); catalogued as rs1304938868, COSV60194937; called by muse, mutect2
- VSTM4 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 26/488 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV100252173; called by muse, mutect2
- WDR62 | c.1313G>T p.R438L | Missense Mutation (SNP) | VAF 29/598 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM107204, COSV99544314; called by muse, mutect2
- APOB | c.5193C>A p.V1731= | Silent (SNP) | VAF 47/978 reads (5%) | catalogued as rs775515832, COSV99268390; called by muse, mutect2
- PTGER2 | c.423C>T p.P141= | Silent (SNP) | VAF 22/437 reads (5%) | catalogued as COSV99817786; called by muse, mutect2
